MMRF case MMRF_1862 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/29818df5-ad86-4e33-8418-7d7be23812e1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.8 years (19,645 days); ISS stage: III; Days to last known disease status: 1,010 days (2.8 years); Days to last follow up: 1,010 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 198 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 728 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 0.45 g/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 11.8 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.78 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 152 µmol/L; Calcium 2.5 mmol/L; Albumin 48 g/L; Total Protein 8.1 g/dL; Glucose 4.84 mmol/L.
- Day 74 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 107 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 12 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 3.95 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.08 mmol/L; Albumin 27 g/L; Total Protein 5.3 g/dL; Glucose 4.35 mmol/L.
- Day 164 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.681 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 93.9 mg/dL; Immunoglobulin G 1.4 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 9.1 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 5.6 g/dL; Glucose 4.57 mmol/L.
- Day 268: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 83.6 mg/dL; Immunoglobulin G 1.47 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 2.71 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 182 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 372 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 3.97 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 5.1 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.39 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.3 g/dL; Glucose 4.95 mmol/L.
- Day 437 (ECOG 2): Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.35 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 22.5 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 556 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1.02 g/L; Beta 2 Microglobulin 8.1 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.79 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 23.2 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.13 mmol/L.
- Day 724 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.54 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 23.2 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 814 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.55 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 4 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 20.3 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 4.51 mmol/L.
- Day 919 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 3.3 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.5 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.85 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 4.79 mmol/L.
- Day 1,010 (ECOG 1): Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.42 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.08 mmol/L; Albumin 24 g/L; Total Protein 4.8 g/dL; Glucose 4.18 mmol/L.

Other clinical attributes
- Day -13: Weight: 76 kg; Height: 164 cm.

Biospecimens (2 samples)
- Sample MMRF_1862_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1862_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
